Gene-level copy-number profile of tumor specimen ALCH-B4CX-TTP1-A from ALCHEMIST case ALCH-B4CX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,268 days).
Specimen ALCH-B4CX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a889fad4-da62-44f9-9fda-f6a4f6e74301.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4CX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/c20bcf56-8e66-4223-8248-64d2a03dc3d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 844; copy number 1: 11,027; copy number 2: 38,976; copy number 3: 7,710; copy number 4: 327; copy number 5: 5; copy number 6: 3; copy number 7: 1; copy number 9: 6; copy number 13: 2; copy number 15: 1; copy number 35: 2.

Homozygous deletions (total copy number 0; autosomes only): 331 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,489,860–120,914,238, 9 genes (within-gene range 0–3): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr9:21,058,771–26,644,595, 76 genes (broad region; genes not listed).
- chr9:42,725,013–43,045,120, 11 genes: BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr9:133,097,720–138,253,217, 219 genes (broad region; genes not listed).
- chr10:27,331,357–27,378,362, 5 genes: AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1.
- chr14:105,467,793–105,470,617, 1 gene (within-gene range 0–2): AL928654.2.
- chr14:105,621,116–105,621,180, 1 gene: MIR8071-1.
- chr15:34,790,230–34,795,549, 1 gene (within-gene range 0–2): ACTC1.
- chr16:10,718,633–10,721,464, 3 genes: MTCYBP33, MTND6P33, MTND5P33.
- chr16:32,475,051–32,622,184, 3 genes: ABCD1P3, AC137800.1, AC137800.2.
- chr20:43,304,555–43,304,679, 1 gene: AL021395.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,696,830–7,741,396, 6 genes, copy number 9: AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5 (within-gene range 2–5): IGHA2, IGHE.
- chr16:32,250,620–32,255,922, 2 genes, copy number 6: AC133485.3, TP53TG3D.
- chr16:32,289,547–32,380,049, 3 genes, copy number 5–35: AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,439,069–32,441,159, 1 gene, copy number 6: PABPC1P13.
- chr21:43,092,956–43,172,805, 6 genes, copy number 5–15: U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 10,187. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
